CCDI case PBCIGR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/ada42446-29cb-4ac9-b951-134db201b65d

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal sarcoma: ICD-O-3 morphology code: 8991/3; Tissue or organ of origin: Liver; Age at diagnosis: 13.5 years (4,929 days).

Biospecimens (3 samples)
- Sample 0DSYE7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DSYEE, 0DSYEN (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
